Gene-level copy-number profile of tumor specimen TCGA-DD-AADJ-01A from TCGA case TCGA-DD-AADJ, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 70.8 years (25,863 days).
Specimen TCGA-DD-AADJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.c61dcfc2-938c-413b-9fe3-a422242b9156.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-AADJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f4b1ade8-3ef2-418e-9874-0ebc73c10bca

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 33; copy number 1: 91; copy number 2: 6,273; copy number 3: 734; copy number 4: 48,402; copy number 5: 1,335; copy number 6: 2,945.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-AADJ-01A-11D-A40Q-01): tumor purity 0.86, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 33 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:9,922,113–10,016,021, 8 genes: LZIC, AL357140.2, NMNAT1, RN7SKP269, TMEM274P, MIR5697, AL603962.1, RBP7.
- chr2:186,162,949–186,163,245, 1 gene: AC104058.1.
- chr3:60,616,822–60,732,636, 5 genes: AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71.
- chr3:114,684,580–114,687,609, 1 gene: ZBTB20-AS2.
- chr3:175,234,861–175,369,621, 2 genes: NAALADL2-AS2, MIR4789.
- chr3:188,688,781–188,688,866, 1 gene: MIR28.
- chr5:104,383,298–105,392,970, 1 gene (within-gene range 0–4): AC099520.1.
- chr5:104,917,492–105,246,364, 2 genes (within-gene range 0–4): AC091987.1, RAB9BP1.
- chr6:2,341,450–2,386,110, 2 genes: HMGN2P28, AL031768.2.
- chr9:109,511,475–109,511,545, 1 gene: MIR3927.
- chr10:76,242,022–76,438,775, 4 genes: RN7SL518P, RNU6-673P, AC012048.1, AC013286.1.
- chr11:10,149,192–10,165,109, 1 gene: AC100763.1.
- chr13:93,818,424–94,025,598, 2 genes: GPC6-AS2, RNA5SP35.
- chr20:14,884,250–14,935,363, 2 genes: MACROD2-AS1, AL138808.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 86. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
